Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A8HI, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A8HI-01A (Primary Tumor).

[page 1 of 6]
REPORT

Collected:

Ordered by:

CLINICAL DIAGNOSIS:

Bladder cancer

FINAL DIAGNOSIS:

RADICAL CYSTECTOMY WITH PELVIC LYMPH NODE DISSECTION; BOWEL RESECTION FOR RIGHT COLON POUCH WITH AUGMENTATION; G-TUBE PLACEMENT:

RIGHT DISTAL URETER (A):
FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- NO HIGH GRADE UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

LEFT DISTAL URETER (B):
FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- NO HIGH GRADE UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

PERIAORTIC LYMPH NODES (C):

FROZEN SECTION DIAGNOSIS:

- MALIGNANT

FINAL DIAGNOSIS:

- METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES (2/2)

URINARY BLADDER, UTERUS, BILATERAL FALLOPIAN TUBES AND OVARIES:

URINARY BLADDER: (SEE AMENDMENT)

- POORLY DIFFERENTIATED UROTHELIAL CARCINOMA INFILTRATING INTO OUTER LAYER OF MUSCULARIS PROPRIA AND MEASURING 3.5 X 3.5 X 3.0 CM IN GREATEST DIMENSION
- MULTIFOCAL PAPILLARY UROTHELIAL CARCINOMA, NUCLEAR GRADE 3/3 WITH AREA OF FOCAL INVASION INTO THE LAMINA PROPRIA
- ALL SURGICAL MARGINS, FREE OF DYSPLASIA OR CARCINOMA
- METASTATIC CARCINOMA IDENTIFIED IN ONE OF THREE LYMPH NODES (1/3) WITH NO EXTRANODAL EXTENSION IDENTIFIED
- LYMPHOVASCULAR INVASION PRESENT

UTERUS, BILATERAL FALLOPIAN TUBES AND OVARIES:

- CERVIX, MILD CHRONIC CERVICITIS AND NABOTHIAN CYST
- ENDOMETRIUM, ATROPHIC, NO HYPERPLASIA OR CARCINOMA IDENTIFIED
- MYOMETRIUM, MICROSCOPIC LEIOMYOMA
- OVARIES, NO SIGNIFICANT LESION FOUND
- FALLOPIAN TUBES, NO SIGNIFICANT LESION FOUND

VAGINAL URETHRAL MARGIN (E):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- NO DYSPLASIA OR CARCINOMA IDENTIFIED

RIGHT PARACAVAL LYMPH NODES (F):

- METASTATIC CARCINOMA IDENTIFIED IN NINE OF 14 LYMPH NODES EXAMINED (9/14)

LEFT COMMON ILIAC LYMPH NODES (G):

- METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES EXAMINED (2/2)

PRESACRAL LYMPH NODES (H):

- METASTATIC CARCINOMA IDENTIFIED IN THREE OF SEVEN LYMPH NODES

*ICD-O-3
Carcinoma, papillary urothelial
8130/3
Site: Bladder NOS
67.9
Jr 11/23/14*

[page 2 of 6]
REPORT

Collected:

Ordered by:

EXAMINED (3/7) WITH EXTRANODAL EXTENSION IDENTIFIED

RIGHT COMMON ILIAC LYMPH NODES (I):

- NO TUMOR IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

RIGHT NODE OF CLOQUET (J):

- NO TUMOR IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

RIGHT EXTERNAL ILIAC LYMPH NODES (K):

- NO TUMOR IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (L):

- METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODES EXAMINED (1 /1)
- LYMPH NODES MEASURING 2.5 CM IN GREATEST DIMENSION

LEFT NODE OF CLOQUET (M):

- METASTATIC CARCINOMA IDENTIFIED IN SIX OF SEVEN LYMPH NODES EXAMINED (6/7)
WITH EXTRANODAL EXTENSION IDENTIFIED

LEFT EXTERNAL ILIAC LYMPH NODES (N):

- METASTATIC CARCINOMA IDENTIFIED IN TWO OF SIX LYMPH NODES EXAMINED (2/6)

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (O):

- METASTATIC CARCINOMA IDENTIFIED IN SIX OF NINE LYMPH NODES EXAMINED (6/9)

RIGHT PRESACRIC LYMPH NODES (P):

- NO TUMOR IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

LEFT PRESACRIC LYMPH NODES (Q):

- NO TUMOR IDENTIFIED , NO LYMPHOID TISSUE

LEFT PROXIMAL URETER (R):

- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

RIGHT PROXIMAL URETER (S):

- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

PATHOLOGIC TNM STAGE: pt2bn2mx

DIAGNOSIS COMMENT:

Immunostain for p53 has been ordered (D5), results of which will be reported in an addendum.

AMENDMENT

This amendment is to clarify the grade of the infiltrating and papillary urothelial carcinomas in the urinary bladder. The remainder of the diagnosis is unchanged.

URINARY BLADDER (D):

- POORLY DIFFERENTIATED UROTHELIAL CARCINOMA, NUCLEAR GRADE 3/4, INFILTRATING INTO OUTER LAYER OF MUSCULARIS PROPRIA AND MEASURING 3.5 X 3.5 X 3.0 CM IN GREATEST DIMENSION
- MULTIFOCAL PAPILLARY UROTHELIAL CARCINOMA, NUCLEAR GRADE 3/4, WITH AREA OF FOCAL INVASION INTO THE LAMINA PROPRIA
- ALL SURGICAL MARGINS, FREE OF DYSPLASIA OR CARCINOMA
- METASTATIC CARCINOMA IDENTIFIED IN ONE OF THREE LYMPH NODES (1/3) WITH NO EXTRANODAL EXTENSION IDENTIFIED
- LYMPHOVASCULAR INVASION PRESENT

[page 3 of 6]
REPORT

Collected:

Ordered by:

INTRAOPERATIVE DIAGNOSIS:

FROZEN SECTION DIAGNOSIS:

AFS: Right distal ureter:
- no tumor identified

BFS: Left distal ureter:
- no tumor identified

CFS: Periaortic node:
- metastatic carcinoma

EFS: Vaginal urethral margin:
- no tumor identified

Signed by:

ELECTRONIC SIGNATURE

GROSS DESCRIPTION:

A: The specimen is received fresh from the O.R. and labeled "Right distal ureter FS". It consists of a segment of ureter that measures 0.6 x 0.5 x 0.5 cm. The specimen is entirely submitted for frozen in a single cassette.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter FS". It consists of a segment of ureter that measures 0.7 x 0.5 x 0.5 cm. The specimen is entirely submitted for frozen in a single cassette.

C: The specimen is received fresh from the O.R. and labeled "Peri-aortic node FS". It consists of a fragment of pale-tan tissue with attached yellow adipose tissue with an overall measurement of 4.0 x 3.0 x 1.5 cm. Sectioning reveals two lymph nodes one measuring 1.6 x 1.4 x 0.5 cm and the other measuring 1.5 x 1.1 x 0.5 cm. Half of the specimen is embedded for frozen. The remaining half of the specimen is saved for research purposes.

D: The specimen is received fresh from the O.R. and labeled "Urinary bladder uterus and bilateral tubes and ovaries". It consists of a radical cystectomy specimen with attached uterus and bilateral ovaries and fallopian tubes with an overall measurement of 29 x 17 x 4.0 cm. The bladder measures 10.7 x 8.0 x 3.0 cm with attached peritoneum that measures 13.0 x 10.0 x 4.0 cm. The peritoneum and outer surface of the bladder are unremarkable. Opening the bladder reveals a thickened bladder wall which measures 1.2 cm and a pink-tan multifocal papillary slightly friable tumor the largest focus measuring 3.5 x 3.5 x 3.0 cm and located at the trigone. This largest focus of tumor appears to involved the urethra and is located 2.2 cm from the vaginal urethral margin. Other foci are seen at the left, right, and posterior bladder wall. Serial sectioning show none of the foci of tumor to invade into the perivesical connective tissue whos radial margin has been inked in blue. The right ureter measures 10.4 cm in length and 0.7 cm in circumference and the left ureter measures 8.0 cm in length and 2.0 cm in circumference. The mucosal surface of the ureter is pink-tan grey and smooth with no lesions identified. The uterus measures 6.8 cm superior to inferior, 4.8 cm right to left and 3.2 cm anterior to posterior. The serosal surface is predominantly smooth with a few tan nodule ranging from 0.2 to 0.5 cm. The cervix measures 1.8 cm in length and 3.8 cm in diameter and is covered by a smooth pink-tan ecto-cervix. The endocervical canal measures 1.5 cm in length and is covered by a tan granular mucosa. The endometrial cavity measures 1.5 cm from cornu to cornu and 3.5 cm in length and is covered by a thin endometrial stripe

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

which averages 0.1 cm. Serial sections to the endomyometrium show a pink-tan firm parenchyma with no significant lesions identified. The right ovary measures 3.6 x 1.8 x 1.0 cm and the left ovary measures 3.4 x 1.8 x 1.0 cm. Both ovaries have a yellow-tan surface with sectioning revealing multiple corpora albicans. The right fallopian tube measures 9 cm in length and 0.4 cm in diameter and the left fallopian tube measures 11 cm in length and 0.5 cm in diameter both fallopian tubes are grossly unremarkable. Careful dissection and palpation of the perivesical adipose tissue reveals rare candidate lymph nodes. At the request of the surgeon, an intraoperative pathologic consultation is performed in order to aid in the care of this patient. Representative sections are submitted in 25 cassettes.

E: The specimen is received fresh from the O.R. and labeled "Urethral margin FS". It consists of a fragment of pink-tan tissue measuring 1.7 x 0.5 x 0.4 cm. The specimen is entirely submitted for frozen.

F: The specimen is received in formalin and labeled "Right para caval L nodes". It consists of multiple fragments of yellow adipose tissue aggregating to 5.0 x 3.5 x 1.8 cm. A few lymph nodes are palpated the largest measuring 3.6 cm in greatest dimension. Representative sections are submitted in five cassettes.

G: The specimen is received in formalin and labeled "L common iliac L nodes". It consists of multiple fragments of yellow-tan fibrous tissue with adherent yellow fatty tissue. The specimen aggregates to 4.5 x 3.0 x 1.5 cm. Multiple lymph nodes are palpated, the largest measuring 1.5 cm in greatest dimension. Representative sections are submitted in three cassettes.

H: The specimen is received in formalin and labeled "Presacral L nodes". It consists of multiple fragments of yellow-tan adipose tissue measuring in aggregate 4.9 x 3.2 x 1.1 cm. A large lymph node is palpated measuring 2.2 cm in greatest dimension. The largest lymph node is entirely submitted in three cassettes.

I: The specimen is received in formalin and labeled "R common iliac L nodes". It consists of a single fragment of yellow-tan adipose tissue measuring 5.0 x 2.0 x 1.5 cm. A large single lymph node is palpated measuring 3.5 cm in greatest dimension. This large lymph node is entirely submitted in two cassettes.

J: The specimen is received in formalin and labeled "R node of cloquet". It consists of a single fragment of yellow adipose tissue measuring 3.3 x 1.5 x 0.8 cm. A single lymph node measuring 1.4 cm in greatest dimension is identified. The specimen is entirely submitted in a single cassette.

K: The specimen is received in formalin and labeled "R external iliac L nodes". It consists of multiple fragments of yellow-tan adipose tissue measuring in aggregate 6.0 x 2.0 x 1.4 cm. A few lymph nodes are palpated, the largest measuring 2.1 cm in greatest dimension. Representative sections are submitted in two cassettes.

L: The specimen is received in formalin and labeled "R obturator/hypogastric L nodes". It consists of multiple fragments of yellow adipose tissue aggregating to 7.2 x 4.0 x 1.0 cm. A few lymph nodes are palpated, the largest measuring 1.1 cm in greatest dimension. Representative sections are submitted in

M: The specimen is received in formalin and labeled "L node of cloquet". It consists of two fragments of tan-brown tissue aggregating to 5.5 x 3.8 x 1.2 cm. Multiple lymph nodes are palpated, the largest measuring 2.1 cm in greatest dimension. Representative sections are submitted in

N: The specimen is received in formalin and labeled "L external iliac L nodes". It consists of multiple fragments of yellow-tan fibrous tissue measuring in

[page 5 of 6]
Collected:

Ordered by:

aggregate 8.5 x 2.0 x 0.9 cm. Multiple lymph nodes are palpated, the largest measuring 1.7 cm in greatest dimension. Representative sections are submitted in two cassettes.

O: The specimen is received in formalin and labeled "L obturator/hypogastric L nodes". It consists of multiple fragments of yellow adipose tissue aggregating to 5.7 x 4.2 x 1.0 cm. A few lymph nodes are palpated, the largest measuring 3.0 cm in greatest dimension. Representative sections are submitted in three cassettes.

P: The specimen is received in formalin and labeled "R presciatic L nodes". It consists of multiple fragments of yellow adipose tissue aggregating to 4.3 x 2.6 x 0.5 cm. A few lymph nodes are palpated, the largest measuring 0.8 cm in greatest dimension. The lymph nodes are submitted intact in a single cassette.

Q: The specimen is received in formalin and labeled "L presciatic L nodes". It consists of multiple fragments of yellow adipose tissue and tan fibroconnective tissue aggregating to 4.9 x 2.0 x 0.9 cm. No palpable lymph nodes are identified. The specimen is entirely submitted in a single cassette.

R: The specimen is received in formalin and labeled "L proximal ureter". It consists of a segment of ureter measuring 1.6 cm in length and 0.5 cm in diameter with attached fibroadipose connective tissue measuring up to 1.6 cm in thickness. The entire segment of ureter is submitted in a single cassette.

S: The specimen is received in formalin and labeled "R proximal ureter". It consists of a segment of ureter measuring 1.4 cm in length and 0.6 cm in diameter. The entire segment of ureter is submitted in a single cassette.

SECTIONS:

AFS: frozen section, right ureter all embedded
BFS: frozen section, left ureter all embedded
CFS: frozen section, periaortic node all embedded
D1: right vesical ureter junction
D2: left vesical ureter junction
D3: tumor to distal vaginal urethral margin
D4: largest focus of tumor to deep margin
D5,6: largest focus of tumor
D7: tumor in left bladder wall
D8: tumor in left bladder wall
D9: tumor in posterior bladder wall
D10: tumor in right bladder wall
D11-13: tumor in posterior bladder wall
D14: normal mucosa from posterior bladder wall
D15: normal mucosa from right bladder wall
D16: normal mucosa from left bladder wall
D17: anterior cervix
D18: posterior cervix
D19: full thickness anterior endomyometrium
D20: full thickness posterior endomyometrium
D21: uterine serosal nodules
D22: right ovary and fallopian tube
D23: left ovary and fallopian tube
D24,25: candidate lymph nodes
EFS: frozen section, vaginal urethral margin
F1-4: largest lymph nodes
F5: intact lymph node
G1: largest lymph node, bisected
G2,3: intact lymph node
H1-3: presacral lymph nodes

[page 6 of 6]
REPORT

Collected:

Ordered by:

I1,2: large right common iliac lymph node
J: right node of Cloquet
K1: largest lymph node, bisected
K2: intact lymph node
L1,2: intact right obturator / hypogastric lymph node
M1-3: largest left lymph node of Cloquet
M4: one lymph node, bisected
M5: intact lymph node
N1,2: each containing two lymph nodes, each bisected
O1,2: largest left obturator / hypogastric lymph nodes
O3: intact lymph nodes
P: right presciatic lymph nodes
Q: left presciatic lymph node
R: left proximal ureter all embedded
S: right proximal ureter all embedded

POST-OPERATIVE DIAGNOSIS:

Same as above

PRE-OPERATIVE DIAGNOSIS:

Bladder cancer

ORDERING PHYSICIAN:

Ordering Physician:

IHPAA Discrepancy		/

Source: NCI Genomic Data Commons file cfbe90d1-7df3-4dfe-be25-9c2307f3f106 (TCGA-XF-A8HI.737E5709-0C1B-488C-B915-84F26A4B86D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).